Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8589, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8589-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

M

[REDACTED] Case ID	Gross Description
[REDACTED]	

[page 2 of 5]
Microscopic Description	Diagnosis Details

[page 3 of 5]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Gastric resection Tumor site: Fundus Tumor size: 9 x 8 x 1 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Lesser omentum Lymph nodes: 1/8 positive for metastasis (Intraabdominal 1/8) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 4 of 5]
ID

114

[page 5 of 5]
Excision date

Source: NCI Genomic Data Commons file 8fd44a0a-c9d3-4f9e-83bb-6b39120b0009 (TCGA-BR-8589.D8D7D51F-CAB5-4734-A753-AEF2CC4BD928.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).